Somatic mutation profile of tumor specimen TCGA-2G-AALO-01A (aliquot TCGA-2G-AALO-01A-12D-A42Y-10) from TCGA case TCGA-2G-AALO, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10e85f65-b234-4a3a-9ec3-f67dd077696d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALO-10A (Blood Derived Normal), aliquot TCGA-2G-AALO-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/393168c9-32d7-4261-a3cc-ab63adfc271c

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMCN1 | c.8968G>A p.G2990S | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMMR | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPK8IP2 | c.2162C>A p.P721H | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MCM3AP | c.1938G>T p.R646S | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGA3 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SNX20 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TNKS | c.3710del p.H1237Pfs*18 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- KCTD1 | c.-15-46189C>A | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- NFIB | c.1245+4114A>T | Intron (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- TM9SF4 | c.-22T>C | 5'UTR (SNP) | VAF 10/58 reads (17%) | catalogued as rs914092101; called by muse, mutect2, varscan2
- ZFAND1 | c.55+14T>A | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
